Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-4856, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-4856-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Accession Number: [REDACTED] Report Status:
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]
PATIENT: [REDACTED]

TCGA-CZ-4856

Resident: [REDACTED]
Pathologist: [REDACTED]

PATHOLOGIC DIAGNOSIS:

LEFT KIDNEY, NEPHRECTOMY (210.5g):
RENAL CELL CARCINOMA, clear cell type, 4.2 cm, involving lower pole, Fuhrman nuclear grade II (of IV).

Tumor is confined to the kidney.
Soft tissue margin of resection is negative for tumor.
Renal vein, renal artery, and ureteral margins are negative for tumor.
No lymphovascular invasion present.

AJCC Stage (6th edition): T1b N0 MX.

REGIONAL LYMPH NODES, BIOPSY:

Four lymph nodes with no tumor present.

EVALUATION OF NON-NEOPLASTIC KIDNEY (NEPHRECTOMY SPECIMEN):
KIDNEY WITH MINOR, NON-SPECIFIC ABNORMALITIES, INCLUDING MILD FOCAL GLOBAL GLOMERULOSCLEROSIS (4% OF TOTAL GLOMERULI)
ARTERIAL AND ARTERIOLAR SCLEROSIS, MILD TO MODERATE

MICROSCOPIC DESCRIPTION:

The sample consists of kidney cortex and medulla. There are up to one hundred ninety six (196) glomeruli present in the sample submitted for light microscopy. Eight (8) glomeruli are globally obsolescent (sclerosed). The preserved glomeruli show normal cellularity and reveal no significant pathological changes. Very mild mesangial expansion and occasional reabsorption granules are recognized. On PAS and [REDACTED] silver methenamine stain, the glomerular basement membranes appear of normal thickness. Tubules are well preserved; occasional tubules are mildly distended and show few hyaline casts. The interstitium shows minimal fibrosis and mononuclear inflammation. Less than 5% of the sample shows tubular atrophy and interstitial fibrosis, as evidenced on the trichrome stains (AFOG). Arteries and arterioles reveal mild to moderate sclerosis of the wall, with focal hyalinosis and mild signs of vasoconstriction in the arteriolar walls.

The non-neoplastic kidney was evaluated by [REDACTED], Renal Pathology Service.

CLINICAL DATA:

History: [REDACTED] with incidental finding of (L) renal mass.
Operation: Not specified.
Operative Findings: None given.
Clinical Diagnosis: Not provided.

TISSUE SUBMITTED:

A/1. (L) kidney - FS.
B/2. Regional nodes.

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patient's name and unit number.

Part A, received fresh in the frozen section lab, labeled "#1. (L) kidney - FS", consists of a left nephrectomy specimen (210.5 gm; 11.7 x 6.5 x 4.8 cm) to include ureter (6.8 cm in length x 0.3 cm in diameter), renal veins (1.4 cm in

[page 2 of 3]
Pathology Report

length x 0.5 cm in diameter each), renal artery (2.3 cm in length x 0.4 cm in diameter), and scant loosely attached perinephric fat (7.2 x 5.2 x 1.7 cm - predominately at the lower pole). The specimen is inked black and bivalved, revealing a golden yellow, focally hemorrhagic, predominately solid encapsulated mass (4.2 x 3.5 x 3.9 cm) within the lower pole, 4.5 cm from the ureter, 1.6 cm from the nearest renal vein margin, and 2.6 cm from the renal artery margin. The mass grossly abuts the renal capsule but does not appear to invade through the capsule into the perinephric fat. Representative sections of the mass are submitted to the tissue bank, cytogenetics, and electron microscopy for special studies. Representative normal cortex is held for future electron microscopy, immunofluorescence, and tissue banking studies. The renal pelvis displays unremarkable tan/white glistening urothelium. The cortical medullary junction is well-demarcated with no other gross lesions identified. No lymph nodes are identified within the scant perihilar or perinephric fat. The adrenal gland is not identified. Photographs are taken.

Micro A1: Ureteral, renal vein, and renal artery margins, (en face), 4 frags total, [REDACTED]
Micro A2: "T1" (tumor quick-fix), 1 frag, [REDACTED]
Micro A3-A4: Deepest extension of mass in relationship to perinephric fat and capsule, 2 frags, [REDACTED]
Micro A5: Focally cystic component of mass to include areas of hemorrhage, 1 frag, [REDACTED]
Micro A6: Mass in relationship to pelvis, 1 frag, [REDACTED]
Micro A7: Mass in relationship to adjacent uninvolved parenchyma, 1 frag, [REDACTED]
Micro A8: Cortical medullary junction, 1 frag, [REDACTED]

Part B, labeled "#2. Regional nodes", consists of a 3.6 x 2.2 x 0.6 cm aggregate of yellow/tan lobulated fat, within which four tan rubbery lymph node candidates (ranging from 0.2 cm up to 1.1 cm in greatest dimension) are identified.

Micro B1: 2 single whole lymph node candidates, 2 frags, [REDACTED]
Micro B2: 2 single whole lymph node candidates, 2 frags, [REDACTED]

[REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Resident Review by [REDACTED]
Final Diagnosis by [REDACTED] Electronically signed on [REDACTED]

[page 3 of 3]
Accession Number: [REDACTED]
Type: Cytogenetics
CASE: [REDACTED]
PATIENT: [REDACTED]
Cytogeneticist
[REDACTED]

KARYOTYPE: 45,XX,der(3)t(3;14)(p174;q271),ins(4;5)(q?31;q2?3q3?2),-14

METAPHASES COUNTED: 15 ANALYZED: 8 SCORED: 7 BANDING: GTG

INTERPRETATION:

All metaphases contained clonal aberrations that included 3p deletion, which is a characteristic finding in renal cell carcinoma, clear cell type.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

?RCC

REPORT by [REDACTED]
Final Diagnosis by [REDACTED] Electronically signed on [REDACTED]

Source: NCI Genomic Data Commons file 761bf0ed-687b-40d0-9105-959af58e36f2 (TCGA-CZ-4856.7B616A12-9D64-4671-8369-815DCBACC3CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).